CGCI case HTMCP-01-02-00013 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/36cbf642-eb58-4d10-b5db-88329b1c25be

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 94 days.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,786 days); Year of diagnosis: 2003; Ann Arbor clinical stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 64 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Chest wall.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Iliac, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 48 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 64 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day 0, day 14.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2: Positive.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD30: Positive.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- TP53: Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 1281 [Blood test normal range upper: 226].

Other clinical attributes
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Weight: 87.3 kg; Height: 175 cm; BMI: 28.5; CD4 count: 82; HIV viral load: 116000.
- Day 14: Risk factors: HIV/AIDS.
- Day 14: Comorbidities: HIV/AIDS.
- Day 64: Nadir CD4 count: 82.

Biospecimens (3 samples)
- Sample HTMCP-01-02-00013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-02-00013-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-02-00013-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Hcv test results: Negative; Haart therapy at diagnosis: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Upper Chest Wall Mass; Extranodal site involvement: 1.
- Tests performed: LDH level: 1281; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: P53 >20%.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-02-00013-10A-01D-124:
- % tumour top: 0
- % tumour bottom: 0
